Somatic mutation profile of tumor specimen TARGET-50-CAAAAR-01A (aliquot TARGET-50-CAAAAR-01A-01D) from TARGET case TARGET-50-CAAAAR, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.9 years (314 days).
Specimen TARGET-50-CAAAAR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48b87bde-618f-43c0-a1cc-f0e84400ce78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-CAAAAR-10A (Blood Derived Normal), aliquot TARGET-50-CAAAAR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3e1be30-94ea-4d9d-a1ae-6c521bdc66b0

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLC1 | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV61415383; called by muse, mutect2, varscan2
- WT1 | c.1063-7_1063del p.X355_splice | Splice Site (DEL) | VAF 51/62 reads (82%) | called by mutect2, pindel, varscan2
